Somatic mutation profile of tumor specimen 0E03VM from CCDI case PBCURB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E03VM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1626d32c-5a54-4a7c-b019-851aff9096cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E03W5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70c8d5a3-ac8a-4ddc-b2be-e0c19a8baf28

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 2, Intron 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOD1 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 168/268 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452486; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 232/503 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CLSTN3 | c.1990G>A p.V664I | Missense Mutation (SNP) | VAF 149/323 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs200290008; called by muse, mutect2, varscan2
- DNAJC2 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 147/355 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs973724298; called by muse, varscan2
- ACTRT1 | c.42T>G p.F14L | Missense Mutation (SNP) | VAF 194/408 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, varscan2
- CDK13 | c.3011C>A p.S1004* | Nonsense Mutation (SNP) | VAF 193/210 reads (92%) | called by muse, mutect2, varscan2
- CELSR1 | c.5838G>T p.E1946D | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CNOT1 | c.1587A>G p.G529= | Splice Region (SNP) | VAF 132/273 reads (48%) | called by muse, mutect2, varscan2
- ETV5 | c.1197A>G p.I399M | Missense Mutation (SNP) | VAF 201/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITGB1 | c.2033A>C p.K678T | Missense Mutation (SNP) | VAF 101/109 reads (93%) | SIFT tolerated (0.12); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- RAD51AP2 | c.2447A>T p.N816I | Missense Mutation (SNP) | VAF 125/366 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- RLF | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 148/347 reads (43%) | called by muse, mutect2, varscan2
- SEMA3C | c.1543C>G p.H515D | Missense Mutation (SNP) | VAF 176/392 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SIPA1L2 | c.1829G>C p.G610A | Missense Mutation (SNP) | VAF 167/420 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STEAP4 | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGM2 | c.995G>T p.W332L | Missense Mutation (SNP) | VAF 152/287 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIA3 | c.396C>T p.D132= | Silent (SNP) | VAF 149/322 reads (46%) | catalogued as rs192636764, COSV99989640; called by muse, mutect2, varscan2
- NADSYN1 | c.1095C>T p.T365= | Silent (SNP) | VAF 103/371 reads (28%) | catalogued as rs547742463, COSV59810868; called by muse, mutect2, varscan2
- PRUNE2 | c.411C>T p.N137= | Silent (SNP) | VAF 204/466 reads (44%) | catalogued as rs753804376; called by muse, mutect2, varscan2
- RAD1 | c.321A>G p.A107= | Silent (SNP) | VAF 196/459 reads (43%) | called by muse, mutect2, varscan2
- SNX15 | c.669C>T p.G223= | Silent (SNP) | VAF 124/390 reads (32%) | catalogued as rs778568224, COSV57248584; called by muse, mutect2, varscan2
- TTC39A | c.1509C>T p.D503= (on ENST00000447632 / NM_001297665.1; = p.D468= on NM_001080494.3) | Silent (SNP) | VAF 215/470 reads (46%) | catalogued as rs752716688, COSV52961549; called by muse, mutect2, varscan2
- XAB2 | c.957C>T p.R319= | Silent (SNP) | VAF 119/228 reads (52%) | catalogued as COSV64321410; called by muse, mutect2, varscan2
- GSN-AS1 | n.3115G>A | RNA (SNP) | VAF 53/128 reads (41%) | catalogued as rs1028166544; called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/44 reads (9%) | called by muse, varscan2
- PGAM5 | c.191+97G>A | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs1428951328; called by mutect2, varscan2
